CCG case CUPP-B5X8 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/15c7d9ce-37d9-4563-a179-e1a4495a2c74

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1928; Vital status: Dead; Days to death: 1,455 days (4.0 years); Year of death: 2012; Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 79.3 years (28,969 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; AJCC staging edition: 8th; AJCC clinical T: T0; AJCC clinical N: N3b; AJCC clinical M: M0; AJCC clinical stage: Stage IVB; AJCC pathologic T: T0; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 14; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R0; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative.
2. Progression of the lymph node (histology not recorded by GDC). Age at diagnosis: 82.0 years (29,935 days); Year of diagnosis: 2010; Days to diagnosis: 966 days (2.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80; ECOG performance status: 1.
- Day 966 (progression): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 966 days (2.6 years).
- Follow-up contact recording only the day: day 1,455.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 162 cm; BMI: 23.6.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1948; Tobacco smoking quit year: 1988.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5X8-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5X8-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
